Gene-level copy-number profile of specimen HCM-CSHL-0601-C25-85A from HCMI case HCM-CSHL-0601-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 61.2 years (22,356 days).
Specimen HCM-CSHL-0601-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f67ea9a4-6e95-432f-8252-81017668def6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0601-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/5ea9384f-51d0-4964-9834-4ae7b93729a2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 681; copy number 2: 9,514; copy number 3: 20,886; copy number 4: 22,261; copy number 5: 2,970; copy number 6: 840; copy number 7: 553; copy number 8: 81; copy number 9: 18; copy number 10: 330; copy number 11: 18; copy number 12: 19; copy number 13: 67; copy number 18: 7; copy number 19: 97; copy number 20: 4; copy number 21: 7; copy number 22: 26; copy number 23: 15.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:22,646,200–23,438,700, 4 genes: LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 608 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:24,704,861–26,285,638, 86 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr6:26,956,932–28,534,955, 95 genes, copy number 10 (broad region; genes not listed).
- chr6:29,672,483–30,172,693, 53 genes, copy number 10: ZFP57, ZDHHC20P1, HLA-F, AL645939.1, HLA-F-AS1, RPL23AP1, MICE, AL645939.2, Y_RNA, IFITM4P, AL645939.4, AL645939.5, AL645939.3, HLA-V, HCG4, HLA-P, RPL7AP7, MICG, HLA-G, HCG4P8, AL645929.2, HCP5B, AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U, HLA-A, AL671277.1, HLA-W, MICD, HCG9, DDX39BP2, MCCD1P2, ZNRD1ASP, HLA-J, AL671277.2, ETF1P1, AL669914.3, AL669914.2, POLR1H, AL669914.4, PPP1R11, RNF39, TRIM31, TRIM31-AS1, AL669914.1, TRIM40, TRIM10, TRIM15.
- chr6:104,017,633–104,026,763, 2 genes, copy number 13: R3HDM2P2, NPM1P10.
- chr6:104,864,464–106,109,939, 14 genes, copy number 9–11: LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, LINC02836, Z97206.1, RN7SKP211, PRDM1.
- chr6:106,100,140–106,100,593, 1 gene, copy number 11: AL022067.1.
- chr6:106,360,717–111,873,452, 120 genes, copy number 10–13 (broad region; genes not listed).
- chr6:112,347,330–112,367,444, 4 genes, copy number 11 (within-gene range 1–11): RFPL4B, RPSAP45, KRT18P65, FEM1AP3.
- chr6:123,216,339–125,445,193, 12 genes, copy number 10: TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1, RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1.
- chr6:125,781,161–126,258,355, 7 genes, copy number 11: NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5.
- chr6:126,340,115–126,683,847, 6 genes, copy number 9–11: CENPW, MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9.
- chr6:128,883,138–129,516,566, 2 genes, copy number 10 (within-gene range 1–11): LAMA2, MESTP1.
- chr6:129,436,875–129,576,047, 3 genes, copy number 10: RNU6-861P, AL356124.1, AL356124.2.
- chr6:133,502,252–133,892,802, 1 gene, copy number 10 (within-gene range 1–10): TARID.
- chr6:133,540,784–142,446,266, 136 genes, copy number 10–23 (broad region; genes not listed).
- chr6:142,748,443–146,437,601, 51 genes, copy number 12–22 (within-gene range 7–22): AL023584.1, HIVEP2, AL023584.2, AL355304.1, LINC01277, AL023581.2, AIG1, AL023581.1, AL136116.2, AL136116.1, AL136116.3, AL031320.1, ADAT2, TUBB8P2, RNA5SP221, PEX3, AL031320.2, VDAC1P8, FUCA2, PHACTR2, PHACTR2-AS1, AL049844.1, LTV1, AL049844.3, AL049844.2, ZC2HC1B, PLAGL1, HYMAI, AL109755.2, AL109755.1, SF3B5, MRPL42P3, STX11, TPT1P4, AL024474.1, UTRN, AL024474.2, AL590704.1, AL513475.1, AL513475.2, EPM2A, RNU1-33P, AL031119.1, AL023806.1, AL023806.2, AL023806.3, FBXO30, FBXO30-DT, SHPRH, GRM1, FUNDC2P3.
- chr6:146,364,931–147,204,614, 11 genes, copy number 12 (within-gene range 4–12): AL035698.1, RAB32, AL359547.1, ADGB, AL359547.2, RNU6-906P, KATNBL1P6, STXBP5-AS1, AL138916.1, AL138916.2, LUADT1.
- chr6:165,987,551–166,113,273, 4 genes, copy number 9: LINC00602, GAPDHP72, AL627443.1, AL627443.2.

Autosomal genes at a single copy (total copy number 1): 681. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
